Somatic mutation profile of tumor specimen C3L-01462-01 (aliquot CPT0085910009) from CPTAC case C3L-01462, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.2 years (24,927 days).
Specimen C3L-01462-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31d30f63-9457-4f2b-98c4-e2253a6023e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01462-31 (Blood Derived Normal), aliquot CPT0086690002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f80b353-99a4-4f65-aa8a-31fe13d1d4f2

The open-access MAF lists 72 somatic variants for this specimen: 53 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 12, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 3, Intron 3, 5'UTR 2, 3'UTR 1, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 78/181 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs869025636, CM044739, CM941372, CM951284, COSV56546928, COSV56549872, COSV56553319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.4837G>A p.E1613K | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs749861523, COSV55791840; called by muse, mutect2, varscan2
- ARHGAP40 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769437937; called by muse, mutect2, varscan2
- ATP6V0A4 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 176/528 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV59473382; called by muse, mutect2, varscan2
- ATRX | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 30/185 reads (16%) | catalogued as COSV64880893; called by muse, mutect2, varscan2
- CACNA1A | c.4956G>T p.E1652D | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV64188627; called by muse, mutect2, varscan2
- CSMD3 | c.7342G>A p.A2448T (on ENST00000297405 / NM_001363185.1; = p.A2344T on NM_052900.3) | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV99823432; called by muse, mutect2, varscan2
- CYLC1 | c.1755G>C p.K585N | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV61410409; called by muse, mutect2, varscan2
- GLRA1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 116/394 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV51007457; called by muse, mutect2, varscan2
- HECTD2 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1488592666; called by muse, mutect2, varscan2
- KASH5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.345); catalogued as COSV71357886; called by muse, mutect2, varscan2
- MATN2 | c.2677C>T p.R893W | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.288); catalogued as rs145754758; called by muse, mutect2, varscan2
- MGA | c.7300C>G p.R2434G (on ENST00000219905 / NM_001164273.1; = p.R2225G on NM_001080541.2) | Missense Mutation (SNP) | VAF 144/480 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54950853; called by muse, mutect2, varscan2
- NGLY1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750077439; called by muse, mutect2, varscan2
- PAPPA2 | c.1441C>G p.L481V | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62776761, COSV62776919; called by muse, mutect2
- PBRM1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 38/97 reads (39%) | catalogued as COSV56268492; called by muse, mutect2, varscan2
- RHOJ | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs755677655, COSV57459616; called by muse, mutect2, varscan2
- RIC3 | c.655A>G p.M219V (on ENST00000309737 / NM_001206671.4; = p.M218V on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.225); catalogued as rs568782352; called by muse, mutect2
- RMDN3 | c.1085A>T p.N362I | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs1474240666; called by muse, mutect2, varscan2
- ROBO3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376257514; called by muse, mutect2, varscan2
- SKA3 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as rs771827485; called by muse, mutect2, varscan2
- ZNF780B | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.745); catalogued as rs750374848; called by muse, mutect2, varscan2
- ABCA2 | c.3670A>G p.I1224V (on ENST00000614293; = p.I1194V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ABCB1 | c.527_530+11del p.X176_splice | Splice Site (DEL) | VAF 47/302 reads (16%) | called by mutect2, pindel, varscan2
- ABCC9 | c.3683C>A p.A1228D | Missense Mutation (SNP) | VAF 115/400 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ATM | c.3994-4G>A | Splice Region (SNP) | VAF 84/247 reads (34%) | called by muse, mutect2, varscan2
- CAPN3 | c.1195A>G p.M399V | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CARMIL3 | c.3660del p.A1221Qfs*7 | Frame Shift Del (DEL) | VAF 49/158 reads (31%) | called by mutect2, pindel, varscan2
- CCDC158 | c.2685_2686dup p.L896Hfs*2 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | called by mutect2, pindel
- CEACAM16 | c.1105A>T p.T369S | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CENPC | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DHX8 | c.2303_2305delinsCACC p.H768Pfs*8 | Frame Shift Ins (INS) | VAF 32/150 reads (21%) | called by pindel, varscan2*
- GLI3 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 214/585 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GMPS | c.395G>T p.S132I | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HPSE | c.813del p.R272Efs*8 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel
- IL1RAP | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- INSRR | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, varscan2
- IPO8 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- KCNC1 | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- KY | c.1223C>A p.T408N | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- LMTK3 | c.3670A>C p.I1224L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- MARS2 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- RALGAPA1 | c.3273_3274dup p.C1092Sfs*8 | Frame Shift Ins (INS) | VAF 12/100 reads (12%) | called by mutect2, pindel
- RGPD4 | c.3955G>T p.D1319Y | Missense Mutation (SNP) | VAF 45/788 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCEL | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC12A7 | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- STX1B | c.789G>C p.K263N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SULF2 | c.2549G>T p.W850L | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TEX44 | c.938del p.G313Afs*67 | Frame Shift Del (DEL) | VAF 78/286 reads (27%) | called by mutect2, pindel, varscan2
- THRAP3 | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 87/254 reads (34%) | called by muse, mutect2, varscan2
- UBXN10 | c.155A>T p.K52I | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13A | c.5067G>C p.K1689N | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- VPS13C | c.8453T>G p.L2818* (on ENST00000644861 / NM_020821.3; = p.L2775* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.4059A>G p.Q1353= | Silent (SNP) | VAF 34/157 reads (22%) | catalogued as rs533442329; called by muse, mutect2, varscan2
- CD28 | c.78G>A p.S26= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs199844145; called by muse, mutect2, varscan2
- DGKA | c.387C>T p.I129= | Silent (SNP) | VAF 8/218 reads (4%) | catalogued as rs1485770287; called by muse, mutect2
- EFL1 | c.2502C>T p.N834= | Silent (SNP) | VAF 76/278 reads (27%) | catalogued as rs777015162; called by muse, mutect2, varscan2
- FNBP4 | c.420T>C p.D140= | Silent (SNP) | VAF 48/128 reads (38%) | called by muse, varscan2
- HERC1 | c.2553C>A p.T851= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- IMPG1 | c.228G>A p.T76= | Silent (SNP) | VAF 72/319 reads (23%) | catalogued as rs372049150, COSV100886392; called by muse, mutect2, varscan2
- MAGEL2 | c.2424T>A p.S808= | Silent (SNP) | VAF 62/192 reads (32%) | called by muse, mutect2, varscan2
- PI4K2A | c.1251T>C p.H417= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs1458855831; called by muse, mutect2, varscan2
- TANK | c.723T>C p.N241= | Silent (SNP) | VAF 25/552 reads (5%) | called by muse, mutect2
- TSHR | c.432G>A p.L144= | Silent (SNP) | VAF 122/311 reads (39%) | called by muse, mutect2, varscan2
- XKR5 | c.1512A>G p.A504= | Silent (SNP) | VAF 37/188 reads (20%) | called by muse, mutect2, varscan2
- AGTPBP1 | c.-58C>T | 5'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- BTBD19 | c.*11G>A | 3'UTR (SNP) | VAF 75/186 reads (40%) | catalogued as rs762061356; called by muse, mutect2, varscan2
- CAV1 | c.195+35C>G | Intron (SNP) | VAF 82/275 reads (30%) | called by muse, mutect2, varscan2
- ITPR3 | c.-46C>T | 5'UTR (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- LTO1 | c.50+164G>T | Intron (SNP) | VAF 13/52 reads (25%) | catalogued as rs553410925; called by muse, mutect2, varscan2
- MAGED1 | c.1782-9del | Intron (DEL) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- TSTD2 | chr9:97633807 G>T | 5'Flank (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
